Somatic mutation profile of tumor specimen MP2PRT-PAVATV-TMP1-A (aliquot MP2PRT-PAVATV-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVATV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,182 days).
Specimen MP2PRT-PAVATV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c593da4-b102-4ae2-8c14-9a9396f6fa94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVATV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVATV-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba4720ca-64f6-4a68-948b-e567d0bcaba8

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.4279C>T p.R1427* | Nonsense Mutation (SNP) | VAF 97/205 reads (47%) | catalogued as rs762339281, COSV100001534; called by muse, mutect2, varscan2
- ERAP2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV65940292; called by muse, mutect2, varscan2
- NEU1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 19/706 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs199697301, COSV57669508; ClinVar: uncertain significance; called by muse, mutect2
- NFX1 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 166/430 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1173812259; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 189/419 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCBP3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 142/334 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1240869164; called by muse, mutect2, varscan2
- SPTBN2 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 68/1004 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as rs536915281, COSV59462696; called by muse, mutect2
- TNXB | c.5657G>A p.R1886H (on ENST00000647633; = p.R1639H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.36); catalogued as rs756221645; called by muse, mutect2
- TP53I11 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 178/388 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs925034859; called by muse, mutect2, varscan2
- TRABD2B | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 143/756 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.139); catalogued as rs1048824037; called by muse, mutect2, varscan2
- CCDC194 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 188/914 reads (21%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- COLEC10 | c.690C>G p.N230K | Missense Mutation (SNP) | VAF 137/343 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- HOXA5 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 144/391 reads (37%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LTBP3 | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 119/648 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- PRKAR1B | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 98/444 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SOX2 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 169/759 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ZNF583 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 55/344 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZSWIM8 | c.1044G>A p.W348* | Nonsense Mutation (SNP) | VAF 173/437 reads (40%) | called by muse, mutect2, varscan2
- POU3F1 | c.888C>T p.F296= | Silent (SNP) | VAF 86/522 reads (16%) | catalogued as rs752086025; called by muse, mutect2, varscan2
- TAS1R2 | c.1314C>T p.F438= | Silent (SNP) | VAF 57/385 reads (15%) | catalogued as rs146531311, COSV64745169, COSV64746686; called by muse, mutect2, varscan2
- ARHGAP31 | c.-476C>T | 5'UTR (SNP) | VAF 112/524 reads (21%) | called by muse, mutect2, varscan2
